Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A43P, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A43P-01A (Primary Tumor).

[page 1 of 4]
Sample

Gender: Male

DOB:

Race: Black

Report Date:

Pathology Report:

16D-0-3
Carcinoma, urothelial, NOS 8120/3
Site: bladder, dome C67.1

Surgical Pathology Report

W
9/29/12

FINAL PATHOLOGIC DIAGNOSIS

A. Left pelvic lymph nodes; dissection:

- Nine lymph nodes, no tumor (0/9).

B. Right pelvic lymph nodes; dissection:

- Six lymph nodes, no tumor (0/6).

C. Urinary bladder, prostate, seminal vesicles and vas deferens;
cystoprostatectomy:

- Bladder with invasive high grade urothelial carcinoma, see pathologic parameters.

- Bladder diverticulum at lateral wall with urothelial carcinoma in situ.

- Prostate with incidental microscopic prostatic adenocarcinoma, see pathologic parameters.

- All resection margins, free of tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Muscularis propria, inner half.
4. Tumor distribution: Unifocal, 2.2 cm at dome.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/15).
9. pTNM: pT2a,N0,MX.

IHPAA Discrepancy		X
Reviewed Initials: Data Reviewed: 8/17/12		

W
8/19/12

this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Radical Prostatectomy Pathologic Parameters

[page 2 of 4]
1. Gleason Score: 3+3=6.
2. Perineural Invasion: Absent.
3. Tumor Location: Peripheral zone - left (slide C26).
4. Tumor Volume Estimate: 1%.
5. High-grade P.I.N.: Multifocal.
6. Seminal Vesicles: Negative for tumor.
7. Extraprostatic extension: Absent.
8. Peripheral Margin: Negative for tumor.
9. Distal (apical) Margin: Negative for tumor.
10. Proximal (basilar) Margin: Negative for tumor.
11. Regional Lymph Nodes (right and left): Negative for tumor (0/15).
12. pTNM: pT2a,N0,MX.

this Checklist utilizes the 7th edition TNM staging system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

xx

☐ MD

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, ☐ M.D., Ph.D.

Electronically Signed Out by ☐MD

Clinical History:

Patient is a -year-old male with malignant neoplasm of the bladder, undergoing a cystoprostatectomy with ileo-conduit surgery.

Specimens Received:

A: Left pelvic lymph node

B: Right pelvic lymph node

C: Bladder, prostate, seminal vesicles, vas deferens

Gross Description:

The specimens are received in three containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "left pelvic lymph node". Received fresh and placed in formalin are multiple, irregular, fibrofatty, soft tissue fragments aggregating to a total of 7.5 x 4 x 1 cm. Ten lymph node candidates are dissected from the specimen ranging in size from 0.3 cm to 2.5 cm. Lymph node candidates are entirely submitted as follows

A1: 5 lymph node candidates

A2: One lymph node, bisected

A3: One lymph node, bisected

[page 3 of 4]
A4: One lymph node, bisected
A5-A6: One lymph node, serially sectioned

B. The second container is additionally identified as, "right pelvic lymph node". Received fresh and placed in formalin are multiple, irregular, fibrofatty, soft tissue fragments aggregating to a total of 6 x 3.5 x 1 cm. Six lymph node candidates are dissected from the specimen ranging in size from 0.4 cm to 2.3 cm. Lymph node candidates are submitted entirely as follows

B1: One lymph node, bisected
B2: One lymph node, serially sectioned
B3: One lymph node, bisected
B4: One lymph node, bisected
B5: 2 possible lymph node candidates

C. The third container is additionally identified as, "Bladder, prostate and seminal vesicles". Received fresh and placed in formalin is a 292.2 g, 17 x 12.5 x 3.4 cm cystoprostatectomy specimen consisting of a 7 x 6 x 2 cm bladder with attached mesenteric fat and a 4.5 x 3.8 x 3.5 cm prostate. The right seminal vesicles measure 2.7 x 1.2 x 0.8 cm and right vas deferens measures 8 cm in length and 0.5 cm in diameter. The left seminal vesicles measures 3 x 1.5 x 0.6 cm and left vas deferens measures 10.5 cm in length and 0.3 cm in diameter. The right ureteral stump measures 1.3 cm, the left measures 1.7 cm, and both demonstrate intact, patent lumens.

The right half of the prostate and bladder is inked blue and the left half is inked black. The bladder and prostate are opened anteriorly along the urethra. The prostate is received with severe disruptions at the apex but it's surrounded by a thin, intact membranous capsule. Sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity with no discrete masses or indurations.

The opened bladder reveals a 2.2 x 2 x 1 cm polypoidal, firm, and white mass, located in the dome of the bladder. On cut section, the mass does not extend into the muscularis propria and measures 2.1 cm from the deep margin of resection. A 3.5 x 2.5 x 2 diverticulum is noted on the left lateral wall. The wall of diverticulum is 0.3 cm and is lined by pink-tan, attenuated, bladder mucosa with no mass lesions or ulcerations. The remainder of the bladder mucosa is wrinkled, pink-tan with a uniform 0.4 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent. Specimen photographs are taken.

Representative sections are submitted as follows:

C1: Right ureter resection margin
C2: Left ureter resection margin
C3: Distal prostatic urethral margin
C4: Prostatic apical margin
C5-C6: Full-thickness section of the tumor (at maximum depth), bisected

[page 4 of 4]
C7-C9: Remaining tumor, submitted entirely.
C10: Bladder mucosa, anterior wall
C11: Bladder, mucosa, trigone
C12: Bladder, mucosa, right lateral wall
C13: Bladder, mucosa, posterior wall
C14: Bladder, mucosa, left lateral wall with portion of the diverticulum
C15: Bladder mucosa, diverticulum
C16: Bladder mucosa, diverticulum
C17- C22: Representative sections of the right half of prostate from apex to base
(C22: Right vas and seminal vesicle)
C23-C28: Representative sections of the left half of prostate from apex to base
(C28: Left vas and seminal vesicle)

xx

[]

Source: NCI Genomic Data Commons file c13ae68d-92b9-4a4e-bc43-8e756af064c6 (TCGA-FD-A43P.8D2D5019-4C09-4B35-AEB9-4B162A47267A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).